Somatic mutation profile of tumor specimen TCGA-06-0878-01A (aliquot TCGA-06-0878-01A-01D-1492-08) from TCGA case TCGA-06-0878, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 74.8 years (27,319 days).
Specimen TCGA-06-0878-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 10e760f4-da6f-489f-a4aa-5ce3d0bb86a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0878-10A (Blood Derived Normal), aliquot TCGA-06-0878-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/47fdbeba-e2db-4645-96fc-a344e8b45f60

The open-access MAF lists 46 somatic variants for this specimen: 31 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 13, RNA 1, Intron 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS20 | c.5216T>A p.I1739K | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV67132442; called by muse, mutect2
- ALLC | c.620G>T p.C207F | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs750179410, COSV52994908, COSV52996213; called by muse, mutect2
- AMY2B | c.1528A>C p.K510Q | Missense Mutation (SNP) | VAF 23/300 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63715421; called by muse, mutect2
- ATP11B | c.1637T>C p.I546T | Missense Mutation (SNP) | VAF 73/261 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1419463650, COSV60029110; called by muse, mutect2, varscan2
- ATP8B4 | c.1264G>T p.D422Y | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as COSV52716485; called by muse, mutect2, varscan2
- BCL2L13 | c.428C>T p.T143I | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (0.42); PolyPhen benign (0.037); catalogued as COSV58225968; called by muse, mutect2, varscan2
- CHGB | c.341G>A p.G114D | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0.031); catalogued as rs777454124, COSV66760679; called by muse, mutect2, varscan2
- CLNK | c.789G>T p.M263I | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as COSV57015624, COSV99906049; called by muse, mutect2, varscan2
- CTNND2 | c.2997T>G p.D999E | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.97); catalogued as COSV58892489; called by muse, mutect2, varscan2
- DOCK2 | c.885G>T p.L295F | Missense Mutation (SNP) | VAF 66/187 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.055); catalogued as COSV56961207; called by muse, mutect2, varscan2
- ERCC1 | c.857T>C p.F286S | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.081); catalogued as rs1004869770, COSV50004329; called by muse, mutect2, varscan2
- FBLN2 | c.2852G>A p.R951H | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.834); catalogued as rs1476684290, COSV55480308; called by muse, mutect2, varscan2
- GBP5 | c.1186C>T p.R396W | Missense Mutation (SNP) | VAF 133/377 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs753752118, COSV58591452; called by muse, mutect2, varscan2
- GOLGA1 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 62/179 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs754268503, COSV65221247; called by muse, mutect2, varscan2
- HSPG2 | c.2275G>A p.G759S | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65972199; called by muse, mutect2, varscan2
- ITGB6 | c.970G>A p.V324M | Missense Mutation (SNP) | VAF 94/246 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as rs751699169, COSV51794629; called by muse, mutect2, varscan2
- KLHL13 | c.335T>A p.M112K | Missense Mutation (SNP) | VAF 51/172 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV53248434; called by muse, mutect2, varscan2
- KRTAP19-1 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 148/359 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.013); catalogued as rs779790994, COSV66861263; called by muse, mutect2, varscan2
- KRTAP20-2 | c.144T>A p.Y48* | Nonsense Mutation (SNP) | VAF 70/199 reads (35%) | catalogued as COSV58183370; called by muse, mutect2, varscan2
- LAMB4 | c.2546G>A p.R849H | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs148837121; called by muse, mutect2, varscan2
- MUC5AC | c.15715G>A p.A5239T | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.739); catalogued as rs1232632668, COSV100611317; called by muse, varscan2
- NCR1 | c.522G>C p.E174D | Missense Mutation (SNP) | VAF 62/193 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as COSV52556827; called by muse, mutect2, varscan2
- NMBR | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 80/152 reads (53%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs767510484, COSV57800816; called by mutect2, varscan2
- PREX2 | c.4421G>A p.R1474K | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV55773414; called by muse, mutect2, varscan2
- RAB4B | c.568G>A p.G190R | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.929); catalogued as rs768325395, COSV63825119; called by muse, mutect2, varscan2
- SCML2 | c.1360C>T p.H454Y | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV52621268; called by muse, mutect2, varscan2
- SEMA3E | c.2009T>G p.L670W | Missense Mutation (SNP) | VAF 71/281 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57092315; called by muse, mutect2, varscan2
- TMPRSS6 | c.904G>A p.V302I | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.452); catalogued as rs1017672724, COSV100696262, COSV60978933; called by muse, mutect2, varscan2
- ZNF692 | c.1059C>A p.H353Q | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60638025; called by muse, mutect2, varscan2
- FAM234A | c.1650_1651del p.S550Rfs*33 | Frame Shift Del (DEL) | VAF 9/77 reads (12%) | called by mutect2, pindel, varscan2
- IGHE | c.44G>C p.C15S | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT tolerated (0.23); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- ATP2C2 | c.1017G>A p.L339= | Silent (SNP) | VAF 37/110 reads (34%) | catalogued as COSV52296650; called by muse, mutect2, varscan2
- CTBP1 | c.1287C>G p.P429= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as rs369378786, COSV52074354; called by muse, varscan2
- DNAH7 | c.1293C>T p.D431= | Silent (SNP) | VAF 157/436 reads (36%) | catalogued as rs370258473; called by muse, mutect2, varscan2
- FCRL3 | c.411A>G p.G137= | Silent (SNP) | VAF 14/384 reads (4%) | catalogued as COSV63841937; called by muse, mutect2
- GHRHR | c.1134C>T p.F378= | Silent (SNP) | VAF 20/288 reads (7%) | catalogued as rs1439938041, COSV58196649; called by muse, mutect2
- HCRTR2 | c.891A>G p.R297= | Silent (SNP) | VAF 25/78 reads (32%) | catalogued as COSV63796140; called by muse, mutect2, varscan2
- LPAR1 | c.174T>G p.T58= | Silent (SNP) | VAF 56/150 reads (37%) | catalogued as COSV62689031; called by muse, mutect2, varscan2
- MYO1H | c.909C>T p.D303= | Silent (SNP) | VAF 25/113 reads (22%) | catalogued as rs768193927, COSV60446146; called by muse, mutect2, varscan2
- NCKAP1L | c.1581C>T p.S527= | Silent (SNP) | VAF 96/248 reads (39%) | catalogued as rs559364211, COSV53207450; called by muse, mutect2, varscan2
- OR8H2 | c.516C>T p.N172= | Silent (SNP) | VAF 158/485 reads (33%) | catalogued as rs763293702, COSV57944151; called by muse, mutect2, varscan2
- PCDHA8 | c.1611G>A p.A537= | Silent (SNP) | VAF 79/251 reads (31%) | catalogued as COSV65327188; called by muse, mutect2, varscan2
- PPFIA2 | c.2745G>A p.A915= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as rs376356533; called by muse, mutect2, varscan2
- TRAF1 | c.576G>A p.G192= | Silent (SNP) | VAF 54/161 reads (34%) | catalogued as rs1057206846, COSV65868543, COSV65869151; called by muse, mutect2, varscan2
- DCHS2 | n.2352G>A | RNA (SNP) | VAF 17/51 reads (33%) | catalogued as COSV59727753; called by muse, varscan2
- GRM8 | c.727+48408C>T | Intron (SNP) | VAF 15/54 reads (28%) | catalogued as rs375234833; called by muse, mutect2
